Somatic mutation profile of tumor specimen ALCH-B0EG-TTP1-A (aliquot ALCH-B0EG-TTP1-A-1-0-D-A694-36) from ALCHEMIST case ALCH-B0EG, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 72.0 years (26,301 days).
Specimen ALCH-B0EG-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 912ec666-4547-4990-a2e4-0e2072cd7f18.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B0EG-NB1-A (Blood Derived Normal), aliquot ALCH-B0EG-NB1-A-1-0-D-A695-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9168f8a8-32f6-4570-8ff4-b78eaaa6c748

The open-access MAF lists 26 somatic variants for this specimen: 17 protein-altering or splice-affecting, 5 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Silent 5, Intron 2, 3'UTR 1, 5'UTR 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXO11 | c.1672C>G p.R558G (on ENST00000403359 / NM_001190274.2; = p.R474G on NM_025133.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/228 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.06); catalogued as COSV100320138; called by muse, mutect2
- GGT5 | c.457C>T p.R153C | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs1161844017, COSV99571590; called by muse, mutect2
- SLC44A5 | c.307C>A p.P103T | Missense Mutation (SNP) | VAF 16/470 reads (3%) | SIFT tolerated (0.08); PolyPhen benign (0.168); catalogued as COSV63774480; called by muse, mutect2
- ABCB4 | c.2146G>T p.V716L | Missense Mutation (SNP) | VAF 18/564 reads (3%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- BCAN | c.1655C>A p.A552E | Missense Mutation (SNP) | VAF 12/128 reads (9%) | SIFT tolerated (0.46); PolyPhen benign (0.109); called by muse, mutect2
- CACNA1I | c.992C>A p.A331D | Missense Mutation (SNP) | VAF 6/149 reads (4%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.711); called by muse, mutect2
- CHIT1 | c.1009G>T p.V337L | Missense Mutation (SNP) | VAF 19/469 reads (4%) | SIFT tolerated (0.2); PolyPhen benign (0.003); called by muse, mutect2
- IGF2BP2 | c.271C>T p.P91S | Missense Mutation (SNP) | VAF 14/284 reads (5%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.656); called by muse, mutect2
- LAMP2 | c.391G>C p.D131H | Missense Mutation (SNP) | VAF 11/366 reads (3%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.515); called by muse, mutect2
- MBTPS2 | c.1266C>A p.S422R | Missense Mutation (SNP) | VAF 11/288 reads (4%) | SIFT tolerated (0.13); PolyPhen benign (0.023); called by muse, mutect2
- RBMXL3 | c.89A>G p.K30R | Missense Mutation (SNP) | VAF 8/219 reads (4%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.494); called by muse, mutect2
- RPL22L1 | c.346G>C p.D116H | Missense Mutation (SNP) | VAF 8/182 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.432); called by muse, mutect2
- SERPINI2 | c.664A>T p.T222S | Missense Mutation (SNP) | VAF 13/219 reads (6%) | SIFT tolerated (0.72); PolyPhen possibly damaging (0.589); called by muse, mutect2
- SLC7A14 | c.1370C>A p.A457D | Missense Mutation (SNP) | VAF 19/468 reads (4%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.99); called by muse, mutect2
- SLITRK4 | c.2084G>C p.S695T | Missense Mutation (SNP) | VAF 9/268 reads (3%) | SIFT deleterious (0.04); PolyPhen benign (0.119); called by muse, mutect2
- TIAM1 | c.3774+1G>C p.X1258_splice | Splice Site (SNP) | VAF 6/129 reads (5%) | called by muse, mutect2
- UBAP2 | c.3329C>T p.A1110V | Missense Mutation (SNP) | VAF 10/208 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.054); called by muse, mutect2
- ALOX5 | c.1995A>G p.P665= | Silent (SNP) | VAF 5/93 reads (5%) | called by muse, mutect2
- HNRNPCL2 | c.351G>T p.R117= | Silent (SNP) | VAF 16/320 reads (5%) | catalogued as COSV60403356; called by muse, mutect2
- MRC1 | c.1806C>A p.A602= | Silent (SNP) | VAF 20/568 reads (4%) | called by muse, mutect2
- SLC7A3 | c.1521G>T p.L507= | Silent (SNP) | VAF 11/354 reads (3%) | called by muse, mutect2
- STMN2 | c.340C>A p.R114= | Silent (SNP) | VAF 9/211 reads (4%) | catalogued as rs1275388476, COSV55218678, COSV55219805; called by muse, mutect2
- AC105942.1 | n.1040-1601G>T | Intron (SNP) | VAF 10/252 reads (4%) | called by muse, mutect2
- CTNS | c.-3A>C | 5'UTR (SNP) | VAF 10/274 reads (4%) | called by muse, mutect2
- KCNA2 | c.*1232A>G | 3'UTR (SNP) | VAF 10/236 reads (4%) | called by muse, mutect2
- PMM1 | c.87+623C>T | Intron (SNP) | VAF 10/300 reads (3%) | called by muse, mutect2
